Somatic mutation profile of tumor specimen TCGA-B0-5706-01A (aliquot TCGA-B0-5706-01A-11D-1534-10) from TCGA case TCGA-B0-5706, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 45.0 years (16,442 days).
Specimen TCGA-B0-5706-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 16496d9c-ffef-45a3-8374-2f081fcf0232.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-5706-11A (Solid Tissue Normal), aliquot TCGA-B0-5706-11A-01D-1534-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/95b18932-410e-45a2-84ac-8ffd37d34f08

The open-access MAF lists 57 somatic variants for this specimen: 44 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 12, Frame Shift Del 6, Nonsense Mutation 3, Frame Shift Ins 1, RNA 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRG6 | c.3163A>T p.S1055C | Missense Mutation (SNP) | VAF 139/639 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51587009; called by muse, mutect2, varscan2
- BCAN | c.2653G>C p.D885H | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.054); catalogued as rs1438314281, COSV100228535, COSV61255604; called by muse, mutect2, varscan2
- BTN3A1 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 46/257 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV50024489; called by muse, mutect2, varscan2
- CDK12 | c.3262C>T p.Q1088* | Nonsense Mutation (SNP) | VAF 20/97 reads (21%) | catalogued as COSV70999356; called by muse, mutect2, varscan2
- CREBBP | c.878T>C p.V293A | Missense Mutation (SNP) | VAF 63/263 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.791); catalogued as rs1239213391, COSV52114673; called by muse, mutect2, varscan2
- FLG | c.5026A>T p.S1676C | Missense Mutation (SNP) | VAF 35/174 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV64236903, COSV64245756; called by muse, mutect2, varscan2
- GRID1 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV60014973; called by muse, mutect2
- GXYLT1 | c.611C>T p.P204L | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770904299, COSV55132811, COSV55144076; called by muse, mutect2, varscan2
- HAUS1 | c.476+1G>A p.X159_splice | Splice Site (SNP) | VAF 43/176 reads (24%) | catalogued as COSV56362775; called by muse, mutect2, varscan2
- HCFC1 | c.6054G>A p.M2018I | Missense Mutation (SNP) | VAF 88/238 reads (37%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV60069590; called by muse, varscan2
- KRT13 | c.643C>G p.L215V | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV55839089; called by muse, mutect2, varscan2
- LETMD1 | c.482T>G p.F161C | Missense Mutation (SNP) | VAF 41/208 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV50396675; called by muse, mutect2, varscan2
- LSM12 | c.230C>A p.P77H | Missense Mutation (SNP) | VAF 90/401 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53232125; called by muse, varscan2
- MAP3K6 | c.2786C>T p.S929F | Missense Mutation (SNP) | VAF 59/291 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.219); catalogued as COSV58870297; called by muse, mutect2, varscan2
- MEGF10 | c.2302G>A p.D768N | Missense Mutation (SNP) | VAF 48/233 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.537); catalogued as rs373093349; called by muse, mutect2, varscan2
- MEGF8 | c.4468G>T p.V1490F (on ENST00000251268 / NM_001271938.2; = p.V1423F on NM_001410.3) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV52075765; called by muse, mutect2, varscan2
- MYO16 | c.5541C>A p.N1847K | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.011); catalogued as COSV62745736; called by muse, mutect2, varscan2
- NANS | c.803T>C p.L268P | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.251); catalogued as rs1388373086, COSV52963001; called by muse, mutect2, varscan2
- NAV3 | c.4033G>A p.V1345M | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.781); catalogued as rs917683869, COSV57063262, COSV99896682; called by muse, mutect2, varscan2
- NUTM1 | c.619T>A p.S207T | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.938); catalogued as COSV61546003; called by muse, mutect2, varscan2
- OPCML | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 59/288 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as rs137852691, COSV59406065; called by muse, mutect2, varscan2
- PARD3 | c.2432A>C p.D811A | Missense Mutation (SNP) | VAF 59/262 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as COSV60745525; called by muse, mutect2, varscan2
- PCNX3 | c.2515G>A p.V839M | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1336138497, COSV63134839, COSV63140586; called by muse, mutect2
- POLG | c.2830G>C p.E944Q | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51519735; called by muse, mutect2, varscan2
- PROS1 | c.388G>T p.G130* | Nonsense Mutation (SNP) | VAF 43/180 reads (24%) | catalogued as COSV62397750, COSV62399911; called by muse, mutect2, varscan2
- PTEN | c.389_392del p.R130Lfs*3 | Frame Shift Del (DEL) | VAF 65/265 reads (25%) | catalogued as COSV64298628; called by mutect2, pindel, varscan2
- RAI14 | c.1851T>G p.S617R | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.073); catalogued as COSV54289671; called by muse, mutect2, varscan2
- SERPINA3 | c.380A>G p.N127S | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.62); PolyPhen benign (0.009); catalogued as rs145819878; called by muse, mutect2, varscan2
- SLC36A1 | c.175G>T p.G59C | Missense Mutation (SNP) | VAF 55/233 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.167); catalogued as COSV54652156; called by muse, mutect2, varscan2
- SPEN | c.3803C>T p.S1268F | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs748429563, COSV65358130; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 9/23 reads (39%) | PolyPhen probably damaging (0.973); catalogued as rs752358616, COSV59562108, COSV59565593; called by muse, mutect2, varscan2
- SYCP2L | c.895G>T p.A299S | Missense Mutation (SNP) | VAF 166/751 reads (22%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.521); catalogued as COSV51650093; called by muse, mutect2, varscan2
- TMEM200A | c.185G>C p.G62A | Missense Mutation (SNP) | VAF 61/431 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51649430; called by muse, mutect2, varscan2
- VHL | c.431_432insTTCTCAATGTTGACGG p.Q145Sfs*4 | Frame Shift Ins (INS) | VAF 54/250 reads (22%) | catalogued as CI1410323, COSV56550145, COSV56559061; called by mutect2, varscan2
- WASHC4 | c.1903A>G p.S635G | Missense Mutation (SNP) | VAF 74/372 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV59888558; called by muse, mutect2, varscan2
- XYLB | c.67G>T p.V23F | Missense Mutation (SNP) | VAF 152/596 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV52911639; called by muse, mutect2, varscan2
- ZBTB6 | c.256C>A p.L86M | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV65409463; called by muse, mutect2, varscan2
- ZFAND5 | c.397C>T p.Q133* | Nonsense Mutation (SNP) | VAF 136/693 reads (20%) | catalogued as COSV52988291, COSV99428532; called by mutect2, varscan2
- ANKRD12 | c.1161del p.E388Kfs*74 | Frame Shift Del (DEL) | VAF 44/246 reads (18%) | called by mutect2, pindel
- CASP8AP2 | c.2003_2004del p.M668Tfs*3 | Frame Shift Del (DEL) | VAF 30/161 reads (19%) | called by mutect2, pindel, varscan2
- FAM126A | c.827_828del p.L276Sfs*4 | Frame Shift Del (DEL) | VAF 38/202 reads (19%) | called by mutect2, pindel, varscan2
- GRM4 | c.1454_1459del p.D485_S486del | In Frame Del (DEL) | VAF 16/103 reads (16%) | called by mutect2, pindel, varscan2
- LRP6 | c.2199del p.K733Nfs*15 | Frame Shift Del (DEL) | VAF 36/195 reads (18%) | called by pindel, varscan2
- ZYG11B | c.1124del p.M375Rfs*16 | Frame Shift Del (DEL) | VAF 23/118 reads (19%) | called by mutect2, pindel, varscan2
- ABCB8 | c.795C>T p.S265= (on ENST00000297504 / NM_001282291.2; = p.S248= on NM_007188.5) | Silent (SNP) | VAF 26/132 reads (20%) | catalogued as COSV52502389; called by muse, mutect2, varscan2
- ABHD18 | c.153C>T p.S51= | Silent (SNP) | VAF 96/435 reads (22%) | catalogued as rs201269910, COSV66293131; called by muse, mutect2, varscan2
- ASPSCR1 | c.270C>T p.N90= | Silent (SNP) | VAF 31/119 reads (26%) | catalogued as rs368306368; called by muse, mutect2, varscan2
- BCAN | c.2652G>A p.E884= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as rs1350215211, COSV61255598; called by muse, mutect2, varscan2
- DNAJC6 | c.354T>C p.T118= | Silent (SNP) | VAF 85/322 reads (26%) | catalogued as COSV54770066; called by muse, mutect2, varscan2
- EHF | c.363G>C p.L121= | Silent (SNP) | VAF 33/185 reads (18%) | catalogued as rs775856876, COSV57667583; called by muse, mutect2, varscan2
- EPHA5 | c.435G>C p.G145= | Silent (SNP) | VAF 31/161 reads (19%) | catalogued as COSV56632317; called by muse, mutect2, varscan2
- MAST4 | c.4278C>T p.H1426= (on ENST00000403625 / NM_001164664.2; = p.H1237= on NM_015183.3) | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs778238525, COSV55116480; called by muse, mutect2, varscan2
- MYADM | c.390C>T p.H130= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as rs771155643, COSV61238635; called by muse, mutect2, varscan2
- RPF1 | c.205C>A p.R69= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV65723930; called by muse, mutect2, varscan2
- SHANK1 | c.198C>T p.D66= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as rs545121253, COSV53242370; called by muse, mutect2, varscan2
- TUBGCP2 | c.930G>A p.L310= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as rs1306165175, COSV53303024; called by muse, mutect2, varscan2
- DCHS2 | n.4949T>A | RNA (SNP) | VAF 38/168 reads (23%) | catalogued as COSV61768312; called by muse, mutect2, varscan2
